Gene-level copy-number profile of tumor specimen TCGA-32-4209-01A from TCGA case TCGA-32-4209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.8 years (14,903 days).
Specimen TCGA-32-4209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c9e50eda-f288-4539-81ec-65a0a1514f7d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-32-4209-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate.
https://portal.gdc.cancer.gov/files/1f711c85-e607-41cc-adfb-b6ca26cd9710

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 16,072; copy number 2: 42,832; copy number 3: 682; copy number 5: 193; copy number 6: 20.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,857,270–233,013,256, 2 genes (within-gene range 0–1): SNORC, NGEF.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 213 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,018,671–152,709,491, 185 genes, copy number 5 (broad region; genes not listed).
- chr1:196,774,813–197,067,260, 8 genes, copy number 5: CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B.
- chr1:197,911,902–199,393,307, 20 genes, copy number 6: LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1.

Autosomal genes at a single copy (total copy number 1): 13,691. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
